Somatic mutation profile of tumor specimen 0DW2W8 from CCDI case PBCNMY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (650 days).
Specimen 0DW2W8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 203961bd-51f1-467f-a60c-09c11d5e293b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW2VN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd4da330-90a7-4e3c-8fbf-cbd3c29447c0

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 5, Silent 5, Splice Region 1, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL2 | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 235/550 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99537386; called by muse, mutect2, varscan2
- CATSPERD | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 24/604 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV101062783; called by muse, mutect2
- FTO | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 84/470 reads (18%) | catalogued as COSV67109768; called by mutect2, varscan2
- GDPD4 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs1039360602; called by muse, mutect2, varscan2
- GDPD4 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs899726571; called by muse, mutect2, varscan2
- KIF1B | c.3640C>G p.Q1214E (on ENST00000377086 / NM_001365952.1; = p.Q1168E on NM_015074.3) | Missense Mutation (SNP) | VAF 135/588 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV55803879; called by muse, varscan2
- OTOGL | c.6614C>T p.A2205V (on ENST00000547103; = p.A2196V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs574033095, COSV54013021; called by muse, mutect2, varscan2
- ACTR5 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 111/412 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 46/938 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LRIG3 | c.2366C>A p.T789N | Missense Mutation (SNP) | VAF 96/425 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MUC16 | c.14894T>A p.I4965K | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); called by muse, mutect2
- MUC17 | c.3845G>T p.S1282I | Missense Mutation (SNP) | VAF 166/623 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRC1 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 224/587 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PROX1 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 98/531 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PTGS1 | c.877del p.L293Cfs*23 | Frame Shift Del (DEL) | VAF 58/246 reads (24%) | called by mutect2, varscan2
- RYR2 | c.10935A>T p.A3645= | Splice Region (SNP) | VAF 59/273 reads (22%) | called by muse, mutect2, varscan2
- SRCAP | c.8833G>A p.A2945T | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FOXI1 | c.42C>T p.C14= | Silent (SNP) | VAF 154/556 reads (28%) | called by muse, mutect2, varscan2
- FTO | c.756T>C p.P252= | Silent (SNP) | VAF 84/458 reads (18%) | called by mutect2, varscan2
- OR51I1 | c.615C>A p.I205= | Silent (SNP) | VAF 126/693 reads (18%) | catalogued as COSV66508989; called by muse, mutect2, varscan2
- RXFP1 | c.1332C>T p.I444= | Silent (SNP) | VAF 94/401 reads (23%) | called by muse, mutect2, varscan2
- SLC22A16 | c.492A>T p.G164= | Silent (SNP) | VAF 117/600 reads (20%) | called by muse, mutect2, varscan2
- AHSA2P | n.1729+17C>T | Intron (SNP) | VAF 33/262 reads (13%) | catalogued as rs1460247516; called by muse, mutect2, varscan2
- ATAD3A | c.528+86del | Intron (DEL) | VAF 6/23 reads (26%) | called by mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 13/98 reads (13%) | called by muse, varscan2
- FGFR1 | c.-36G>A | 5'UTR (SNP) | VAF 157/611 reads (26%) | catalogued as rs200766494; called by muse, mutect2, varscan2
- MATN3 | c.1169-56G>C | Intron (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- TSPEAR | c.543-60G>T | Intron (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
